CCDI case PBCILI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f7e399bd-57a4-4c7c-b0d6-4bf2e4bc87e4

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 9.3 years (3,405 days).

Biospecimens (3 samples)
- Sample 0DSMWS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSMY3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSMYG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
